Somatic mutation profile of tumor specimen 0DVCF4 from CCDI case PBCLNF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.3 years (105 days).
Specimen 0DVCF4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be347562-05c4-4d1d-bd09-418bdf24f316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b023e00-8d5a-4d4b-9459-6dcbbb2b61d5

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN6 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 60/553 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs782600635, COSV59684448; called by muse, varscan2
- ELAC2 | c.-6G>A | 5'UTR (SNP) | VAF 42/252 reads (17%) | catalogued as rs1474895977; called by muse, varscan2
